Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3378, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3378-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN INFORMATION

Collected:
Received:
Reported:

Accession #:
Acct / Reg #:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Left kidney, nephrectomy:
Renal carcinoma.

Tumor Characteristics:

1. Histologic type: Clear cell adenocarcinoma.
2. Tumor site: Posterior aspect of mid left kidney.
3. Tumor size: 5.5 x 5.0 x 4.0 cm.
4. Macroscopic extent of tumor: Limited to kidney.
5. Nuclear grade: Fuhrman grade: 3/4.
6. Lymphovascular space invasion: No.
7. Transcapsular invasion: No.
8. Renal vein invasion: No.
9. Venacaval invasion: Not resected.
10. Adrenal gland: Not identified.

Surgical Margin Status:

1. Soft tissue margins: Negative for tumor.
2. Ureteral margin: Negative for tumor.
3. Vascular Margins: Negative for tumor.

Lymph Node Status:

1. No lymph nodes identified.

Other Significant Findings:

pTNM stage: T1N0MX, Stage I.

Electronic Signature

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis:

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Left kidney

SPECIMEN DATA

[page 2 of 2]
GROSS DESCRIPTION:

Received in a single container labeled [REDACTED] is a tan-yellow lobular mass of adipose tissue, 18.0 x 12.0 x 9.0 cm in greatest dimension. No adrenal gland is noted with the specimen. Sectioning reveals a 310 gram left kidney, 12.0 x 8.5 x 7.5 cm displaying a bulging mass on the posterior surface in the mid body. The hilar region displays an abundant amount of adhered tan-yellow lobular adipose tissue as well as a portion of ureter extending 8.0 cm in length and 0.6 cm in diameter. No lymph nodes are noted. Bivalving the kidney reveals a pale renal cortex and medulla. The cortex averages 0.5 cm. A central tan-yellow well circumscribed lobular mass is noted and is 5.5 x 5.0 x 4.0 cm in greatest dimension. No invasion of the surrounding pelvis or vessels are grossly seen. No other lesions are noted. Representative samples submitted in eight cassettes labeled [REDACTED] as follows: vesicle and ureter margins-1; inked capsule-2; pelvic wall-3; lesion-4 to 7; normal renal tissue-8.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 05d06427-f0ea-4740-8640-c4c2af7bd377 (TCGA-A3-3378.97EED0BE-150E-44C3-B4C0-6D062434E44A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).